Somatic mutation profile of tumor specimen 0DNFU6 from CCDI case PBCBGK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Mixed germ cell tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.0 years (1,454 days).
Specimen 0DNFU6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 460a467e-572d-4f9f-a25b-99b7e07a0240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DNFTW (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e9029522-69bd-4e0a-9516-8a2b71d39503

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPP1R13B | c.2606A>G p.N869S | Missense Mutation (SNP) | VAF 527/1194 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99162608; called by muse, mutect2, varscan2
